Somatic mutation profile of tumor specimen TARGET-10-PARUGV-09A (aliquot TARGET-10-PARUGV-09A-01D) from TARGET case TARGET-10-PARUGV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (571 days).
Specimen TARGET-10-PARUGV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 754ff707-16d5-4705-8a1e-1b479bbb0ab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUGV-10A (Blood Derived Normal), aliquot TARGET-10-PARUGV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a309c470-5853-442a-bd0b-8222942cffb2

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR10S1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs768212335, COSV73343001; called by mutect2, varscan2
- CACNB2 | c.1199C>T p.S400F (on ENST00000324631 / NM_201596.3; = p.S345F on NM_000724.4) | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC168 | c.12319G>A p.E4107K | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.44); called by muse, mutect2
- IPO9 | c.3076G>T p.G1026C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2
